TCGA case TCGA-GU-A766 — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: BLN - UT Southwestern Medical Center at Dallas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e7680a8e-1c0e-426b-abd8-d0d8e7d0e5aa

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Transitional cell carcinoma: ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 62.4 years (22,774 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 480 days (1.3 years).
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: No; Lymph nodes positive: 0; Lymph nodes tested: 19; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 171 days; Disease response: With Tumor.
- Days to follow up: 480 days (1.3 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 102 kg; Height: 175 cm; BMI: 33.3.

Exposures
- Chemical exposure type: Aluminum; Occupation duration years: 30; Occupation type: Building Frame and Related Trades Workers.
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Grandfather; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-GU-A766-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 380 mg.
  Slide TCGA-GU-A766-01A-01-TSA: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-GU-A766-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-GU-A766-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: Disabled; Occupation primary: Building / construction; Occupation primary chemical exposure: Aluminum; Occupation primary industry: Aluminum; Tobacco smoking history indicator: 1; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Neck; Anatomic organ subdivision: Wall NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: No; Incidental prostate cancer indicator: No; New tumor event diagnosis indicator: No.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 480 days; disease-specific survival: no event (censored), 480 days; progression-free interval: no event (censored), 480 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-GU-A766-01A-11D-A32A-01): tumor purity 0.39, ploidy 1.96, whole-genome doublings 0.
